Somatic mutation profile of tumor specimen TCGA-FS-A1ZY-06A (aliquot TCGA-FS-A1ZY-06A-11D-A197-08) from TCGA case TCGA-FS-A1ZY, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 73.9 years (26,996 days).
Specimen TCGA-FS-A1ZY-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f22cc61-b9d5-4097-a1df-0b7451471dcd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZY-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZY-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28da0c21-60ab-404a-a6de-ef5907bb2f9f

The open-access MAF lists 36 somatic variants for this specimen: 21 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 14, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 89/127 reads (70%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKAR | c.450T>G p.I150M | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs1160235916, COSV55613507; called by muse, mutect2, varscan2
- ANKRD35 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62910549; called by muse, varscan2
- APPL2 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as rs558853233, COSV51590909; called by muse, mutect2, varscan2
- BRAT1 | c.601C>T p.H201Y | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV61395672; called by muse, mutect2, varscan2
- CD163L1 | c.2558G>A p.G853E | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV58017441; called by muse, mutect2, varscan2
- CYTIP | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201390719, COSV51634105; called by muse, mutect2, varscan2
- DGKD | c.2884C>G p.R962G (on ENST00000264057 / NM_152879.3; = p.R918G on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs1374116045, COSV51052251; called by muse, mutect2, varscan2
- DNAI2 | c.89A>G p.D30G | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56759232; called by muse, mutect2, varscan2
- GRIA2 | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.869); catalogued as COSV52392635; called by muse, mutect2, varscan2
- KRT73 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs1210935768, COSV59837684, COSV99988492; called by muse, mutect2, varscan2
- NOTCH4 | c.5968C>T p.L1990F | Missense Mutation (SNP) | VAF 185/431 reads (43%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.005); catalogued as rs1185576654, COSV66681205; called by muse, mutect2, varscan2
- OR5F1 | c.127C>A p.L43I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs372205796, COSV53547736; called by muse, mutect2, varscan2
- OR6K2 | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.811); catalogued as COSV62743571; called by muse, mutect2, varscan2
- PDE3A | c.3007T>G p.S1003A | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62974432; called by muse, mutect2, varscan2
- PGK2 | c.1007G>T p.W336L | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV59164125; called by muse, mutect2, varscan2
- PMM1 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs764459233, COSV53447972; called by muse, mutect2, varscan2
- POTEE | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as rs1390475550, COSV58232713; called by muse, mutect2, varscan2
- PTGER4 | c.964C>A p.P322T | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56721123; called by muse, mutect2, varscan2
- SIGLEC14 | c.1086G>T p.R362S | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); catalogued as COSV99707664; called by muse, mutect2, varscan2
- SIGLEC14 | c.1085G>A p.R362K | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.314); catalogued as COSV99707665; called by muse, mutect2, varscan2
- ANKRD35 | c.471G>C p.L157= | Silent (SNP) | VAF 120/478 reads (25%) | catalogued as COSV62910543; called by muse, varscan2*
- DLGAP2 | c.1056G>A p.S352= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs373693698; called by muse, mutect2, varscan2
- GBF1 | c.1347C>T p.T449= (on ENST00000369983 / NM_001377137.1; = p.T448= on NM_004193.3) | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as COSV64145506; called by muse, mutect2, varscan2
- GRIN2B | c.1884C>T p.S628= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV74206190; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.201G>A p.G67= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs372545819; called by muse, mutect2, varscan2
- MYH2 | c.4701C>T p.I1567= | Silent (SNP) | VAF 81/92 reads (88%) | catalogued as COSV55439780, COSV55440332; called by muse, mutect2, varscan2
- NAT9 | c.372C>T p.A124= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs555556955, COSV52853491; called by muse, mutect2, varscan2
- NAXD | c.834G>A p.S278= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs199637796, COSV57286514; called by muse, mutect2, varscan2
- RFX4 | c.210G>A p.E70= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV63504981; called by muse, mutect2, varscan2
- RPTOR | c.2511C>T p.I837= | Silent (SNP) | VAF 98/156 reads (63%) | catalogued as COSV60809770; called by muse, varscan2
- STX6 | c.534C>T p.G178= | Silent (SNP) | VAF 42/180 reads (23%) | catalogued as COSV51112314; called by muse, mutect2, varscan2
- SYNDIG1L | c.528G>T p.L176= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs568113424, COSV59047674; called by muse, mutect2, varscan2
- SYNM | c.1176T>G p.G392= | Silent (SNP) | VAF 120/288 reads (42%) | catalogued as COSV60371095; called by muse, mutect2, varscan2
- ZNF804A | c.279G>A p.R93= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs747273502, COSV56436508, COSV56471908; called by muse, mutect2, varscan2
- OR8A1 | c.-22C>G | 5'UTR (SNP) | VAF 23/29 reads (79%) | catalogued as COSV52508906, COSV52509421; called by muse, mutect2, varscan2
